Somatic mutation profile of tumor specimen ALCH-B066-TTP1-A (aliquot ALCH-B066-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B066, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.4 years (25,366 days).
Specimen ALCH-B066-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59a94de7-96e8-4b7a-bac5-4f65241893e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B066-NB1-A (Blood Derived Normal), aliquot ALCH-B066-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/665dd7f2-86d7-46ed-8111-6128ad9e3e65

The open-access MAF lists 411 somatic variants for this specimen: 270 protein-altering or splice-affecting, 79 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 79, Intron 31, Nonsense Mutation 22, RNA 12, Frame Shift Del 8, 3'UTR 8, 5'Flank 7, Splice Site 7, Splice Region 6, 5'UTR 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.11677C>G p.P3893A | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); catalogued as rs549072288, COSV71288095; called by muse, mutect2, varscan2
- ABCC12 | c.2776C>T p.H926Y | Missense Mutation (SNP) | VAF 76/749 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV60912522, COSV60917542; called by muse, mutect2, varscan2
- ADCY3 | c.1478T>G p.I493S | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99568331; called by muse, mutect2
- ALOX12B | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59877269; called by muse, mutect2, varscan2
- ALPK1 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 76/308 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as rs775561725; called by muse, mutect2, varscan2
- AMPH | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391062409, COSV57748367; called by muse, mutect2
- AOAH | c.820T>C p.W274R | Missense Mutation (SNP) | VAF 101/535 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756383676; called by muse, mutect2, varscan2
- AP1G2 | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 57/506 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV99846062; called by muse, mutect2, varscan2
- APBA3 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868124631; called by muse, mutect2
- APOB | c.10717C>G p.L3573V | Missense Mutation (SNP) | VAF 59/642 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.044); catalogued as COSV51945769; called by muse, mutect2
- BPIFB1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs975429750; called by muse, mutect2
- CASKIN2 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs780367601; called by muse, mutect2, varscan2
- CDK14 | c.631G>C p.E211Q (on ENST00000380050 / NM_001287135.2; = p.E193Q on NM_012395.3) | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99724064; called by muse, mutect2, varscan2
- CDK4 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as COSV99226151; called by muse, mutect2, varscan2
- CEP128 | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs773597804, COSV55378656; called by muse, mutect2, varscan2
- CHRM3 | c.999C>A p.S333R | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV55093552; called by muse, varscan2
- CHRNA3 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1192780226; called by muse, mutect2
- COL11A1 | c.986A>T p.N329I | Missense Mutation (SNP) | VAF 50/544 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as COSV62172145; called by muse, mutect2
- CPN2 | c.1468G>C p.V490L | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV60469556; called by muse, mutect2, varscan2
- CSMD3 | c.4736C>A p.P1579H (on ENST00000297405 / NM_001363185.1; = p.P1475H on NM_052900.3) | Missense Mutation (SNP) | VAF 104/595 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52198184, COSV52274800; called by muse, mutect2, varscan2
- CUBN | c.8419G>A p.G2807R | Missense Mutation (SNP) | VAF 89/451 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV100912007; called by muse, mutect2, varscan2
- CYBB | c.45+1del p.X15_splice | Splice Site (DEL) | VAF 94/361 reads (26%) | catalogued as CD105653, CS065534, CS102659, CS991363; called by mutect2, pindel, varscan2
- DIS3L2 | c.2228G>T p.R743L | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs947355512; called by muse, mutect2, varscan2
- DOCK4 | c.5549G>A p.G1850E | Missense Mutation (SNP) | VAF 65/423 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as COSV70243863; called by muse, mutect2, varscan2
- DPEP3 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs779732917; called by muse, mutect2, varscan2
- EAPP | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 53/364 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV99164235; called by muse, mutect2, varscan2
- EEF2K | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.024); catalogued as COSV53780985; called by muse, mutect2
- EGFR | c.3115-1G>C p.X1039_splice | Splice Site (SNP) | VAF 48/596 reads (8%) | catalogued as COSV99288113; called by muse, mutect2
- EGLN2 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs891573349; called by muse, mutect2, varscan2
- EP300 | c.6262C>T p.R2088W | Missense Mutation (SNP) | VAF 101/560 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201569846, COSV54329503; called by muse, mutect2, varscan2
- EXOSC5 | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as COSV55370676, COSV55372173; called by muse, mutect2, varscan2
- EYS | c.1873C>A p.H625N | Missense Mutation (SNP) | VAF 94/666 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.134); catalogued as COSV101005054; called by muse, mutect2, varscan2
- FAM133B | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 56/447 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99065893; called by muse, mutect2, varscan2
- FAM47C | c.1823C>A p.P608Q | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV63724476; called by muse, varscan2
- FYB1 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs749688119, COSV60955036; called by muse, mutect2
- GREB1 | c.1016-2A>G p.X339_splice | Splice Site (SNP) | VAF 43/246 reads (17%) | catalogued as COSV52186808; called by mutect2, varscan2
- GRIA2 | c.1271C>G p.S424C | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52399730, COSV99644334; called by muse, mutect2, varscan2
- HLA-DQA1 | c.480G>C p.E160D | Missense Mutation (SNP) | VAF 112/772 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs764703448; called by muse, varscan2
- HLA-G | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64406687; called by muse, mutect2
- HPSE2 | c.1212G>C p.L404F | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100984935; called by muse, mutect2
- IGSF10 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 148/567 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs201983963; called by muse, mutect2, varscan2
- IGSF11 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100676961; called by muse, varscan2
- INSL3 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs1054350739, COSV57953345; called by muse, mutect2, varscan2
- IRGC | c.1058G>C p.G353A | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.542); catalogued as COSV99746157; called by muse, mutect2, varscan2
- KRT24 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52881225; called by muse, mutect2, varscan2
- KRT76 | c.1007C>A p.T336K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60121112; called by muse, mutect2, varscan2
- KRT84 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs867590669, COSV57773071; called by muse, mutect2, varscan2
- LAMA3 | c.3184A>T p.N1062Y | Missense Mutation (SNP) | VAF 128/823 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV58066965; called by muse, mutect2, varscan2
- LPO | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 42/620 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1312023104, COSV51860346; called by muse, mutect2
- MIOS | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 33/511 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60767110; called by muse, mutect2
- MOG | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV100973034; called by muse, mutect2, varscan2
- MORN5 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65648402; called by muse, mutect2
- MUC16 | c.1646C>A p.P549Q | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as COSV67441664; called by muse, mutect2
- MYH2 | c.3256C>T p.L1086F | Missense Mutation (SNP) | VAF 81/422 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs770066931; called by muse, mutect2, varscan2
- MYH4 | c.4179C>A p.A1393= | Splice Region (SNP) | VAF 68/298 reads (23%) | catalogued as COSV99701893; called by muse, mutect2, varscan2
- MYLK | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 50/508 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs537224715, COSV60616251; ClinVar: uncertain significance; called by muse, mutect2
- NIPA2 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.035); catalogued as COSV100508724; called by muse, mutect2
- NLRP1 | c.3395G>A p.W1132* | Nonsense Mutation (SNP) | VAF 66/622 reads (11%) | catalogued as COSV52558146; called by muse, mutect2
- NPHP4 | c.3142G>A p.A1048T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs767810266; called by muse, mutect2, varscan2
- NPTX2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs1217095980, COSV55719360; called by muse, mutect2
- ODF1 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 78/983 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV53432604; called by muse, mutect2
- OFD1 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs780521580; ClinVar: benign; called by muse, mutect2, varscan2
- OR1S1 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 71/323 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100515297; called by muse, mutect2, varscan2
- OR4A5 | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 81/515 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100157392; called by muse, mutect2, varscan2
- OR4N2 | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60049827; called by muse, mutect2, varscan2
- OVCH1 | c.2047G>T p.V683L | Missense Mutation (SNP) | VAF 60/558 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV58960132; called by muse, mutect2, varscan2
- PABPC3 | c.800A>T p.Q267L | Missense Mutation (SNP) | VAF 58/337 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs775790977, COSV55800605; called by muse, mutect2, varscan2
- PANX1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 90/590 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1489364016; called by muse, mutect2, varscan2
- PCDH11X | c.3571C>A p.Q1191K | Missense Mutation (SNP) | VAF 205/645 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV100015901, COSV104403233, COSV53466208; called by muse, mutect2, varscan2
- PCSK6 | c.842G>C p.G281A | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100083330; called by muse, mutect2
- PEG3 | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 43/516 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV55637352; called by muse, mutect2
- PGM3 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 31/571 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as rs775939917, COSV52283838; called by muse, mutect2
- PKHD1L1 | c.4261A>G p.T1421A | Missense Mutation (SNP) | VAF 52/425 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV65742162; called by muse, mutect2, varscan2
- POSTN | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 111/583 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.751); catalogued as rs117790304; called by muse, mutect2, varscan2
- PPP2R1B | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59535022; called by muse, mutect2
- PROS1 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67777260; called by muse, mutect2
- PTEN | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 80/418 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64310876; called by muse, mutect2, varscan2
- RANBP6 | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs976544886; called by muse, mutect2
- RASGRF2 | c.2846_2848del p.E949del | In Frame Del (DEL) | VAF 38/220 reads (17%) | catalogued as rs1296144548; called by pindel, varscan2
- SEMA4A | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1461418667, COSV100740778; called by muse, mutect2, varscan2
- SLC18A2 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 112/572 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs776549404; called by muse, mutect2, varscan2
- SLFN11 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748813058; called by muse, mutect2, varscan2
- SNTG1 | c.1078G>T p.V360L | Missense Mutation (SNP) | VAF 127/756 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV52429815, COSV52433113; called by muse, mutect2, varscan2
- SPOCK1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 78/532 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99968233; called by muse, mutect2, varscan2
- SPTA1 | c.4645G>T p.D1549Y | Missense Mutation (SNP) | VAF 68/736 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV63752094; called by muse, mutect2
- SRSF11 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1486451553; called by muse, mutect2, varscan2
- STRN4 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs771337652; called by muse, mutect2, varscan2
- SVOP | c.282G>T p.W94C | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV54465611; called by muse, mutect2, varscan2
- SYNGR4 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs1343998199, COSV61225592; called by muse, mutect2, varscan2
- TANGO6 | c.777G>C p.L259F | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV55771439; called by muse, mutect2
- TBX22 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100960971; called by muse, mutect2, varscan2
- TDRD5 | c.2548A>T p.T850S | Missense Mutation (SNP) | VAF 75/380 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54238424; called by muse, mutect2, varscan2
- TGM4 | c.1760C>G p.P587R | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260879150, COSV99942412; called by muse, mutect2, varscan2
- THAP9 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56355645; called by muse, mutect2, varscan2
- TMEM108 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 72/507 reads (14%) | catalogued as COSV58883630; called by muse, mutect2, varscan2
- TP53 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | catalogued as CM107390, COSV52689258; called by muse, mutect2, varscan2
- USH2A | c.3932C>T p.S1311L | Missense Mutation (SNP) | VAF 104/624 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs79279902, CM080597, COSV56361403; called by muse, mutect2, varscan2
- VWC2 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); catalogued as rs1288743178; called by muse, mutect2, varscan2
- WDR17 | c.1421G>T p.R474L | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs781583255; called by muse, mutect2, varscan2
- XIRP2 | c.5771A>G p.D1924G (on ENST00000628543; = p.D2099G on NM_152381.6) | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1016535349; called by muse, varscan2
- ZNF208 | c.1021T>A p.Y341N | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV68111768; called by muse, mutect2, varscan2
- ZNF548 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 76/502 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV60241549; called by muse, mutect2, varscan2
- ZNF708 | c.1655G>C p.R552T | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as COSV63606807; called by muse, mutect2
- ABCA3 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2302T>A p.W768R | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADGRL3 | c.105C>A p.H35Q | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AIF1L | c.32-3C>T | Splice Region (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- AMBRA1 | c.377A>T p.H126L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- AMDHD1 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ANGPT4 | c.941A>C p.K314T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ANKUB1 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANO3 | c.1916T>A p.L639Q | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARF5 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP33 | c.3226G>T p.A1076S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARHGAP42 | c.2524A>G p.I842V | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- ATP1B1 | c.651A>C p.R217= | Splice Region (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2
- BAZ2B | c.5818G>T p.G1940* | Nonsense Mutation (SNP) | VAF 34/321 reads (11%) | called by muse, mutect2, varscan2
- BOD1L1 | c.9012A>C p.R3004S | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BPIFB6 | c.97+2T>C p.X33_splice | Splice Site (SNP) | VAF 35/162 reads (22%) | called by muse, mutect2, varscan2
- C16orf78 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2
- C1orf131 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); called by muse, mutect2
- C6 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 50/644 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2
- C9 | c.476+8T>C | Splice Region (SNP) | VAF 144/749 reads (19%) | called by muse, mutect2, varscan2
- CADPS2 | c.2897C>G p.A966G | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CCDC39 | c.2503C>T p.H835Y | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2
- CCER2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- CDH3 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 114/573 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR1 | c.8206-3C>T | Splice Region (SNP) | VAF 26/164 reads (16%) | called by muse, varscan2
- CEP85L | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 27/272 reads (10%) | called by muse, mutect2
- CFAP43 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CFAP69 | c.1624T>C p.S542P | Missense Mutation (SNP) | VAF 81/477 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLSPN | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- COL16A1 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CPS1 | c.2960-1G>C p.X987_splice | Splice Site (SNP) | VAF 76/570 reads (13%) | called by muse, mutect2, varscan2
- CPS1 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 79/576 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXCL2 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.077); called by muse, mutect2
- DCHS1 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DEPDC5 | c.1683G>A p.M561I | Missense Mutation (SNP) | VAF 31/393 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.195); called by muse, mutect2
- DLL4 | c.1606G>C p.V536L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- DOCK2 | c.5005del p.E1669Nfs*2 | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | called by mutect2, pindel, varscan2
- DPP10 | c.853-2A>T p.X285_splice | Splice Site (SNP) | VAF 15/187 reads (8%) | called by muse, mutect2
- DPY19L4 | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- DRC1 | c.1891G>T p.A631S | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- DYNC2H1 | c.1068A>G p.I356M | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EML5 | c.1426C>G p.L476V | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.22); called by muse, mutect2
- EPG5 | c.3532C>T p.Q1178* | Nonsense Mutation (SNP) | VAF 34/450 reads (8%) | called by muse, mutect2
- ETV3L | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FARP2 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- FIGNL1 | c.271G>T p.G91* | Nonsense Mutation (SNP) | VAF 82/518 reads (16%) | called by muse, mutect2, varscan2
- FLG | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 64/552 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- FYCO1 | c.2512A>G p.N838D | Missense Mutation (SNP) | VAF 88/402 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GABRG1 | c.230del p.N77Ifs*7 | Frame Shift Del (DEL) | VAF 18/149 reads (12%) | called by mutect2, pindel, varscan2
- GBP5 | c.1161T>A p.D387E | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GFRA3 | c.1068C>A p.F356L | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GLIS1 | c.955A>T p.T319S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2
- GOLGB1 | c.7610G>T p.R2537I | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.1896T>A p.C632* | Nonsense Mutation (SNP) | VAF 67/526 reads (13%) | called by muse, mutect2, varscan2
- GUCA1C | c.410T>A p.L137* | Nonsense Mutation (SNP) | VAF 46/303 reads (15%) | called by muse, mutect2, varscan2
- HCRTR2 | c.253A>T p.M85L | Missense Mutation (SNP) | VAF 60/597 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- HDAC9 | c.3024C>A p.S1008R (on ENST00000441542 / NM_178425.3; = p.S1005R on NM_178423.3) | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSF2 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 69/388 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HTR3E | c.934T>A p.F312I (on ENST00000415389 / NM_001256613.1; = p.F327I on NM_182589.2) | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ICE1 | c.5272G>T p.E1758* | Nonsense Mutation (SNP) | VAF 39/283 reads (14%) | called by muse, mutect2, varscan2
- IGLL1 | c.119del p.R40Pfs*24 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | called by mutect2, varscan2
- IL26 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- INSC | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KCNAB3 | c.596A>T p.N199I | Missense Mutation (SNP) | VAF 70/303 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNQ3 | c.1791A>T p.Q597H | Missense Mutation (SNP) | VAF 102/572 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF14 | c.2077A>G p.R693G | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KLHL33 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.131); called by muse, mutect2
- KPRP | c.843C>A p.S281R | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRP2 | c.59T>A p.L20Q | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- LYPLAL1 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MADCAM1 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEB5 | c.140_141delinsA p.L47* | Frame Shift Del (DEL) | VAF 49/277 reads (18%) | called by pindel, varscan2*
- MAPK14 | c.682+3A>G | Splice Region (SNP) | VAF 43/329 reads (13%) | called by muse, mutect2, varscan2
- METTL17 | c.1003del p.H335Mfs*8 | Frame Shift Del (DEL) | VAF 90/420 reads (21%) | called by mutect2, pindel, varscan2
- MINK1 | c.1808A>G p.Q603R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MRO | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTMR4 | c.2090G>T p.S697I | Missense Mutation (SNP) | VAF 45/570 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.081); called by muse, mutect2
- MUC19 | c.62A>G p.H21R | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- MYH3 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 61/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO7B | c.3116C>A p.S1039* | Nonsense Mutation (SNP) | VAF 37/388 reads (10%) | called by muse, mutect2
- MYO9A | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NEB | c.19366C>T p.P6456S | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEUROD4 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 56/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFATC2 | c.311C>A p.A104E | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- NKAIN3 | c.576G>C p.M192I | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NKX6-3 | c.347dup p.Q117Pfs*18 | Frame Shift Ins (INS) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- NRAP | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 25/214 reads (12%) | called by muse, mutect2, varscan2
- OAS3 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 64/242 reads (26%) | called by muse, mutect2, varscan2
- OBSCN | c.12697C>T p.H4233Y | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- OR10D3 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- OR11H6 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 32/443 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- OR14J1 | c.942C>G p.C314W | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- OR2A25 | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 88/580 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- OR5T3 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 75/545 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR6B3 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR6T1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 60/560 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OTOG | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- PCBP1 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCSK6 | c.2444C>T p.T815I | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- PDE5A | c.1952T>G p.L651R | Missense Mutation (SNP) | VAF 126/530 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PICALM | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- PKHD1 | c.1561G>T p.V521F | Missense Mutation (SNP) | VAF 75/692 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PLEKHA1 | c.62del p.N21Tfs*53 | Frame Shift Del (DEL) | VAF 29/206 reads (14%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.3911A>T p.Q1304L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- PMS2 | c.1087T>A p.F363I | Missense Mutation (SNP) | VAF 92/503 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- POTEA | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- PPFIA1 | c.3512C>T p.S1171F | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, varscan2
- PPM1M | c.325C>G p.P109A (on ENST00000296487; = p.P270A on NM_144641.4) | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PRAMEF6 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 62/1136 reads (5%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.831); called by muse, mutect2
- PTGS2 | c.327G>C p.L109F | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2
- PURG | c.518C>G p.T173R | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- R3HDM1 | c.2926C>G p.L976V | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RALYL | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 96/662 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- RAVER1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RBL1 | c.3080G>A p.R1027K | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RECQL | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RELCH | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 54/620 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- RIMS1 | c.647C>A p.S216* | Nonsense Mutation (SNP) | VAF 46/406 reads (11%) | called by muse, mutect2
- RNF213 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RRAGA | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2
- RSPRY1 | c.1499T>C p.L500P | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- RYR2 | c.10960G>A p.E3654K | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SACS | c.9902T>G p.L3301R | Missense Mutation (SNP) | VAF 76/369 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCG3 | c.1150A>T p.K384* | Nonsense Mutation (SNP) | VAF 31/205 reads (15%) | called by muse, mutect2, varscan2
- SDR42E1 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SENP6 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 58/660 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLC43A2 | c.718A>C p.M240L | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SLC4A2 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SLC5A9 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 71/434 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A15 | c.1054del p.V352Cfs*12 | Frame Shift Del (DEL) | VAF 101/663 reads (15%) | called by mutect2, pindel, varscan2
- SP3 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2
- SPATA31A6 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 114/603 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNE1 | c.10145+2T>A p.X3382_splice (on ENST00000367255 / NM_182961.4; = p.X3389_splice on NM_033071.3) | Splice Site (SNP) | VAF 66/670 reads (10%) | called by muse, mutect2
- TBC1D16 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBX22 | c.1089C>A p.Y363* | Nonsense Mutation (SNP) | VAF 165/581 reads (28%) | called by muse, mutect2, varscan2
- TERF2 | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TET3 | c.3121C>G p.Q1041E | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.13); called by muse, mutect2
- THBS2 | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 56/607 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2
- TIMELESS | c.1708T>G p.C570G | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TLN1 | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 94/433 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TLNRD1 | c.464G>C p.R155P | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- TLR4 | c.2409del p.R804Gfs*41 (on ENST00000355622 / NM_138554.5; = p.R764Gfs*41 on NM_003266.4) | Frame Shift Del (DEL) | VAF 51/285 reads (18%) | called by mutect2, pindel, varscan2
- TMEM114 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- TNXB | c.6554G>T p.G2185V (on ENST00000647633; = p.G1938V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP63 | c.284G>T p.C95F | Missense Mutation (SNP) | VAF 125/854 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- TRAPPC6A | c.11C>A p.T4N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRDN | c.1034T>A p.I345N | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRIP11 | c.2696C>G p.S899C | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TTPA | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBGCP6 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UGT2B4 | c.251C>G p.T84S | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2
- USH2A | c.8662G>T p.E2888* | Nonsense Mutation (SNP) | VAF 106/623 reads (17%) | called by muse, mutect2, varscan2
- VPS18 | c.2294A>T p.Q765L | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- WAC | c.419G>T p.S140I | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZBTB20 | c.1087G>T p.A363S (on ENST00000474710 / NM_001164342.2; = p.A290S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZFC3H1 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 117/838 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ZFHX4 | c.5397A>T p.Q1799H | Missense Mutation (SNP) | VAF 88/556 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZHX2 | c.1322C>G p.A441G | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF107 | c.983A>G p.Y328C | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ZNF22 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 56/300 reads (19%) | called by muse, mutect2, varscan2
- ZNF394 | c.1208A>G p.K403R | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF433 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- ZNF460 | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF534 | c.1537G>T p.G513C (on ENST00000332323 / NM_001143939.3; = p.G500C on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- ZNF649 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ZNF711 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- ZNF850 | c.62G>A p.W21* | Nonsense Mutation (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- ABCA8 | c.4281G>A p.T1427= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as rs778446566, COSV52198022, COSV99286400; called by muse, mutect2, varscan2
- ABCA8 | c.3858A>G p.G1286= | Silent (SNP) | VAF 45/405 reads (11%) | called by muse, mutect2, varscan2
- ABLIM2 | c.729G>A p.Q243= | Silent (SNP) | VAF 28/228 reads (12%) | called by muse, mutect2, varscan2
- AK5 | c.771T>C p.R257= (on ENST00000354567 / NM_174858.3; = p.R231= on NM_012093.4) | Silent (SNP) | VAF 37/491 reads (8%) | called by muse, mutect2
- AMER3 | c.1434G>C p.L478= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV58471314; called by muse, mutect2, varscan2
- ANKRD30B | c.1270C>A p.R424= | Silent (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- ARFGEF2 | c.4116G>A p.Q1372= | Silent (SNP) | VAF 98/1061 reads (9%) | called by muse, mutect2
- ATF5 | c.528G>T p.G176= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- ATIC | c.1194A>T p.S398= | Silent (SNP) | VAF 36/358 reads (10%) | called by muse, mutect2
- ATP1A4 | c.2193G>A p.L731= | Silent (SNP) | VAF 19/200 reads (10%) | called by muse, mutect2, varscan2
- AVP | c.162G>T p.G54= | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- BAZ1A | c.3207A>C p.T1069= | Silent (SNP) | VAF 77/525 reads (15%) | called by muse, mutect2, varscan2
- CELF2 | c.762G>T p.L254= (on ENST00000416382 / NM_001025077.3; = p.L261= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/345 reads (11%) | called by muse, mutect2
- CELSR1 | c.7992C>T p.I2664= | Silent (SNP) | VAF 47/245 reads (19%) | called by muse, mutect2, varscan2
- CHD7 | c.7252C>A p.R2418= | Silent (SNP) | VAF 65/407 reads (16%) | catalogued as CM060916, CM130248; called by muse, mutect2, varscan2
- CHI3L2 | c.165A>C p.L55= | Silent (SNP) | VAF 38/560 reads (7%) | called by muse, mutect2
- CMTR1 | c.1227C>T p.F409= | Silent (SNP) | VAF 54/429 reads (13%) | catalogued as rs1257021706, COSV65091717; called by muse, mutect2, varscan2
- COL14A1 | c.2496C>G p.P832= | Silent (SNP) | VAF 31/247 reads (13%) | called by muse, mutect2, varscan2
- COL5A3 | c.4704G>A p.A1568= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53406872; called by muse, mutect2, varscan2
- CROCC | c.462C>T p.S154= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs1318880450; called by muse, mutect2, varscan2
- CYB5R4 | c.54C>G p.V18= | Silent (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- CYP4A22 | c.18G>A p.L6= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs1300590452; called by muse, mutect2, varscan2
- DDC | c.87C>A p.V29= | Silent (SNP) | VAF 147/775 reads (19%) | catalogued as COSV63567214; called by muse, mutect2, varscan2
- DDX19A | c.954G>A p.E318= | Silent (SNP) | VAF 42/449 reads (9%) | called by muse, mutect2
- DOCK3 | c.4341C>A p.R1447= | Silent (SNP) | VAF 89/456 reads (20%) | catalogued as COSV56526545; called by muse, mutect2, varscan2
- ELF4 | c.1710G>C p.L570= | Silent (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- ERBB2 | c.2115G>A p.A705= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as rs1326179459, COSV54065457; called by muse, mutect2, varscan2
- FBN3 | c.5613C>T p.L1871= | Silent (SNP) | VAF 44/415 reads (11%) | called by muse, mutect2
- FBXL18 | c.1392G>T p.S464= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV101154605; called by muse, mutect2, varscan2
- FREM1 | c.5943C>T p.I1981= | Silent (SNP) | VAF 38/275 reads (14%) | called by muse, mutect2, varscan2
- FTMT | c.585C>T p.T195= | Silent (SNP) | VAF 104/516 reads (20%) | catalogued as rs974967744, COSV100360417; called by muse, mutect2, varscan2
- GLB1 | c.255C>T p.P85= | Silent (SNP) | VAF 102/434 reads (24%) | called by muse, mutect2, varscan2
- GRID2IP | c.3213G>A p.L1071= | Silent (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- HIBCH | c.975A>G p.V325= | Silent (SNP) | VAF 66/578 reads (11%) | catalogued as rs763847759; called by muse, mutect2, varscan2
- IGF2R | c.7269G>T p.S2423= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as COSV63626540, COSV63628395; called by muse, mutect2, varscan2
- ILK | c.666G>C p.L222= | Silent (SNP) | VAF 72/822 reads (9%) | called by muse, mutect2
- KALRN | c.1512G>T p.V504= | Silent (SNP) | VAF 34/592 reads (6%) | called by muse, mutect2
- KCNMB4 | c.549G>A p.V183= | Silent (SNP) | VAF 56/656 reads (9%) | catalogued as rs773451756, COSV50693113; called by muse, mutect2
- LINC00634 | c.204G>T p.L68= | Silent (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- LRRC66 | c.1659G>T p.V553= | Silent (SNP) | VAF 136/525 reads (26%) | catalogued as COSV58635316; called by muse, mutect2, varscan2
- MAGI2 | c.336C>T p.L112= | Silent (SNP) | VAF 34/374 reads (9%) | catalogued as COSV62671636; called by muse, mutect2
- MCM6 | c.12G>T p.A4= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- MSI1 | c.351G>T p.S117= | Silent (SNP) | VAF 27/347 reads (8%) | called by muse, mutect2
- MUC19 | c.1257T>A p.P419= | Silent (SNP) | VAF 50/278 reads (18%) | called by muse, mutect2, varscan2
- MYO5A | c.2553C>T p.F851= | Silent (SNP) | VAF 54/547 reads (10%) | called by muse, mutect2
- NEFL | c.24G>A p.P8= | Silent (SNP) | VAF 35/327 reads (11%) | catalogued as rs1227374739, COSV99647810; called by muse, mutect2, varscan2
- OR2M5 | c.132C>A p.V44= | Silent (SNP) | VAF 56/378 reads (15%) | called by muse, mutect2, varscan2
- OR2T12 | c.759C>A p.G253= | Silent (SNP) | VAF 44/580 reads (8%) | called by muse, mutect2
- OR51E1 | c.942C>T p.H314= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs549451979; called by muse, mutect2
- OR8B4 | c.588G>A p.L196= | Silent (SNP) | VAF 45/490 reads (9%) | called by muse, mutect2
- OR8G5 | c.105T>C p.Y35= | Silent (SNP) | VAF 31/330 reads (9%) | catalogued as rs1296936797; called by muse, mutect2
- PAN3 | c.1308G>A p.P436= | Silent (SNP) | VAF 46/457 reads (10%) | catalogued as rs563703969; called by muse, mutect2
- PARP12 | c.1113C>T p.F371= | Silent (SNP) | VAF 91/557 reads (16%) | catalogued as COSV54934369; called by muse, mutect2, varscan2
- PCDH17 | c.3315C>T p.S1105= | Silent (SNP) | VAF 95/447 reads (21%) | called by muse, mutect2, varscan2
- PCDHB6 | c.732G>A p.E244= | Silent (SNP) | VAF 77/380 reads (20%) | called by muse, mutect2, varscan2
- PPP6R1 | c.966G>A p.P322= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs773784867; called by muse, mutect2, varscan2
- PSCA | c.9C>G p.G3= | Silent (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
- RPP38 | c.532C>T p.L178= | Silent (SNP) | VAF 40/406 reads (10%) | called by muse, mutect2, varscan2
- SATL1 | c.513A>G p.Q171= (on ENST00000395409; = p.Q358= on NM_001012980.2) | Silent (SNP) | VAF 37/120 reads (31%) | called by muse, mutect2, varscan2
- SBK2 | c.870T>A p.P290= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- SHCBP1L | c.834A>G p.A278= | Silent (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2, varscan2
- SLC15A5 | c.108T>C p.S36= | Silent (SNP) | VAF 98/480 reads (20%) | called by muse, mutect2, varscan2
- SP3 | c.564C>T p.F188= | Silent (SNP) | VAF 40/730 reads (5%) | catalogued as COSV59465668, COSV59469605; called by muse, mutect2
- SYNJ2 | c.2649C>A p.S883= | Silent (SNP) | VAF 91/908 reads (10%) | called by muse, mutect2
- TAF4B | c.1731C>T p.S577= | Silent (SNP) | VAF 32/388 reads (8%) | called by muse, mutect2
- TBX5 | c.54C>T p.D18= | Silent (SNP) | VAF 36/396 reads (9%) | catalogued as COSV59866397; called by muse, mutect2
- TIMM10B | c.60C>G p.V20= | Silent (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- TNN | c.804G>T p.L268= | Silent (SNP) | VAF 30/132 reads (23%) | called by muse, varscan2
- TNR | c.2475C>G p.T825= | Silent (SNP) | VAF 53/356 reads (15%) | called by muse, mutect2, varscan2
- TRIM6 | c.63C>G p.L21= | Silent (SNP) | VAF 30/494 reads (6%) | catalogued as COSV99546238; called by muse, mutect2
- TRRAP | c.4653G>T p.G1551= (on ENST00000359863 / NM_001244580.1; = p.G1533= on NM_003496.3) | Silent (SNP) | VAF 38/411 reads (9%) | called by muse, mutect2
- TUT7 | c.2562G>A p.E854= | Silent (SNP) | VAF 69/331 reads (21%) | called by muse, mutect2, varscan2
- VAV1 | c.603G>A p.E201= | Silent (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- VPS35L | c.1305C>T p.F435= | Silent (SNP) | VAF 43/410 reads (10%) | catalogued as COSV51988723; called by muse, mutect2, varscan2
- ZNF208 | c.3462A>T p.S1154= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- ZNF324B | c.1284C>T p.A428= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs761606764, COSV60741849; called by muse, mutect2, varscan2
- ZNF436 | c.777C>T p.F259= | Silent (SNP) | VAF 28/286 reads (10%) | called by muse, mutect2
- ZNF536 | c.2871G>A p.E957= | Silent (SNP) | VAF 37/336 reads (11%) | called by muse, mutect2, varscan2
- ZNF730 | c.340A>C p.R114= | Silent (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- ABCC13 | n.544G>T | RNA (SNP) | VAF 52/332 reads (16%) | called by muse, mutect2, varscan2
- ABCC13 | n.545G>T | RNA (SNP) | VAF 53/335 reads (16%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+6234C>T | Intron (SNP) | VAF 42/265 reads (16%) | catalogued as rs1024502428; called by muse, mutect2, varscan2
- AC007952.2 | chr17:19093239 C>T | 5'Flank (SNP) | VAF 63/584 reads (11%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2853G>A | RNA (SNP) | VAF 157/1620 reads (10%) | called by muse, mutect2
- AC114741.1 | n.169C>T | RNA (SNP) | VAF 46/552 reads (8%) | called by muse, mutect2
- AC116655.1 | n.257A>G | RNA (SNP) | VAF 33/330 reads (10%) | called by muse, mutect2, varscan2
- ADGRE4P | n.2538C>T | RNA (SNP) | VAF 61/282 reads (22%) | called by muse, mutect2, varscan2
- AGK | c.-2A>G | 5'UTR (SNP) | VAF 32/200 reads (16%) | called by mutect2, varscan2
- AL132655.6 | chr20:58840219 C>G | 5'Flank (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- AL358334.1 | n.29-7378C>T | Intron (SNP) | VAF 53/443 reads (12%) | called by muse, mutect2, varscan2
- ARL6IP6 | c.401-48C>T | Intron (SNP) | VAF 10/160 reads (6%) | catalogued as COSV100423997; called by muse, mutect2
- ARMC5 | c.1864+254C>T | Intron (SNP) | VAF 7/43 reads (16%) | called by mutect2, varscan2
- ASB10 | chr7:151187445 C>T | 5'Flank (SNP) | VAF 14/106 reads (13%) | catalogued as rs1563579093; called by muse, mutect2, varscan2
- BANP | c.1345-535A>T | Intron (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- CARMIL3 | chr14:24050924 del G | 5'Flank (DEL) | VAF 47/329 reads (14%) | called by mutect2, pindel, varscan2
- CASC3 | c.260-25dup | Intron (INS) | VAF 23/164 reads (14%) | called by mutect2, varscan2
- CELSR1 | c.7760-264C>T | Intron (SNP) | VAF 30/125 reads (24%) | catalogued as rs774907027; called by muse, mutect2, varscan2
- CNOT2 | c.1240+17G>T | Intron (SNP) | VAF 60/708 reads (8%) | called by muse, mutect2
- CNTNAP2 | c.1898-254T>C | Intron (SNP) | VAF 17/164 reads (10%) | catalogued as COSV100674009; called by muse, mutect2, varscan2
- DGAT1 | c.677-15C>G | Intron (SNP) | VAF 4/25 reads (16%) | catalogued as rs782637933; called by muse, mutect2, varscan2
- DHX40 | c.*118A>G | 3'UTR (SNP) | VAF 67/281 reads (24%) | catalogued as rs536785200; called by muse, mutect2, varscan2
- DPP6 | c.627+21029G>T | Intron (SNP) | VAF 68/328 reads (21%) | catalogued as rs375756767; called by muse, mutect2, varscan2
- EIF3IP1 | n.286A>T | RNA (SNP) | VAF 99/746 reads (13%) | called by muse, mutect2, varscan2
- EMBP1 | n.1005A>G | RNA (SNP) | VAF 24/175 reads (14%) | called by muse, mutect2, varscan2
- F13A1 | c.131-51A>T | Intron (SNP) | VAF 24/253 reads (9%) | called by muse, mutect2
- GDF6 | c.*35G>A | 3'UTR (SNP) | VAF 13/149 reads (9%) | catalogued as rs754843511; called by muse, mutect2
- GLDC | c.1262-24dup | Intron (INS) | VAF 108/708 reads (15%) | called by mutect2, pindel, varscan2
- HAX1 | c.316+42G>C | Intron (SNP) | VAF 18/211 reads (9%) | called by muse, mutect2
- HCN1 | c.-4G>A | 5'UTR (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.*65G>T | 3'UTR (SNP) | VAF 30/156 reads (19%) | called by muse, varscan2
- HIPK1 | chr1:113929531 C>G | 5'Flank (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- IZUMO4 | c.537-25C>T | Intron (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- KCNC2 | c.*1988C>G | 3'UTR (SNP) | VAF 324/815 reads (40%) | catalogued as COSV54380497; called by muse, varscan2
- KCNC2 | c.*1916C>T | 3'UTR (SNP) | VAF 356/905 reads (39%) | catalogued as COSV100128653; called by muse, varscan2
- KDM5C | c.2061+21C>G | Intron (SNP) | VAF 10/286 reads (3%) | called by muse, mutect2
- KEL | c.1772-31G>T | Intron (SNP) | VAF 94/576 reads (16%) | called by muse, mutect2, varscan2
- KLF6 | c.*216C>G | 3'UTR (SNP) | VAF 18/97 reads (19%) | catalogued as rs1330852460; called by muse, mutect2, varscan2
- MMP26 | c.-145+93159G>T | Intron (SNP) | VAF 42/198 reads (21%) | catalogued as COSV59034029; called by muse, mutect2, varscan2
- MPRIP | c.2164-4151_2164-4150del | Intron (DEL) | VAF 43/219 reads (20%) | called by mutect2, pindel, varscan2
- NCR2 | c.531-33G>T | Intron (SNP) | VAF 9/47 reads (19%) | catalogued as COSV66100118; called by muse, mutect2, varscan2
- NDUFAF5 | c.*355G>T | 3'UTR (SNP) | VAF 90/549 reads (16%) | called by muse, mutect2, varscan2
- NPIPB1P | n.1051G>T | RNA (SNP) | VAF 104/573 reads (18%) | called by muse, varscan2
- OR2W5 | n.652C>T | RNA (SNP) | VAF 68/381 reads (18%) | called by muse, mutect2, varscan2
- PENK | c.138+17G>C | Intron (SNP) | VAF 32/207 reads (15%) | catalogued as rs1313899861; called by muse, mutect2, varscan2
- PKD1L1 | c.7174-269C>G | Intron (SNP) | VAF 39/362 reads (11%) | called by muse, varscan2
- PMS2CL | n.955G>T | RNA (SNP) | VAF 67/449 reads (15%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.330+69T>C | Intron (SNP) | VAF 72/366 reads (20%) | called by muse, mutect2, varscan2
- PROKR2 | c.*16C>G | 3'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- RBCK1 | c.168-268G>T | Intron (SNP) | VAF 82/454 reads (18%) | called by muse, mutect2, varscan2
- SDAD1 | c.196-44G>A | Intron (SNP) | VAF 47/322 reads (15%) | catalogued as rs1487774655; called by muse, mutect2, varscan2
- SLC26A4 | c.164+34G>A | Intron (SNP) | VAF 5/39 reads (13%) | catalogued as rs1480524363, COSV99707612; called by muse, mutect2, varscan2
- SSPOP | n.15353A>T | RNA (SNP) | VAF 49/314 reads (16%) | called by muse, mutect2, varscan2
- SYNE1 | c.9972+34A>T | Intron (SNP) | VAF 83/486 reads (17%) | called by muse, mutect2, varscan2
- THNSL2 | chr2:88171257 C>T | 5'Flank (SNP) | VAF 32/200 reads (16%) | called by muse, varscan2
- TTC14 | c.858-40A>G | Intron (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.10361-5134G>C | Intron (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- UBE2C | c.-25C>T | 5'UTR (SNP) | VAF 20/267 reads (7%) | catalogued as rs1189825290; called by muse, mutect2
- WRAP73 | c.922+54G>T | Intron (SNP) | VAF 21/229 reads (9%) | called by muse, mutect2
- ZBTB37 | chr1:173866931 C>T | 5'Flank (SNP) | VAF 27/396 reads (7%) | called by muse, mutect2
- ZFAND5 | c.-48G>T | 5'UTR (SNP) | VAF 38/184 reads (21%) | called by muse, mutect2, varscan2
- ZNF160 | c.16-596G>C | Intron (SNP) | VAF 24/353 reads (7%) | catalogued as rs1037881000; called by muse, mutect2
